Surgical pathology report (de-identified scan), TCGA case TCGA-HC-7736, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site International Genomics Consortium, specimen TCGA-HC-7736-01A (Primary Tumor).

[page 1 of 3]
QC Pathologist:

FINAL PATHOLOGIC DIAGNOSIS:

A. Right side pelvic lymph node dissection:

Eight benign hyperplastic regional lymph nodes (0/8).

B. Left side pelvic lymph node dissection:

Five benign hyperplastic regional lymph nodes (0/5).

C. Radical prostatectomy:

Carcinoma.

Tumor Characteristics:

1. Histologic type: Adenocarcinoma, conventional type.

2. Prostate size: 5.0 x 4.5 x 4.0 cm with weight of 70.9 grams.

3. Tumor quantitation: Tumor involves approximately 10% of gland volume.

4. Gleason grade:

a. Primary pattern: 3/5.

b. Secondary pattern: 4/5.

c. Total Gleason score: 7/10.

5. Extraprostatic extension: See comment below.

6. Seminal vesicle involvement: Not identified.

7. Lymphovascular space invasion: Not identified.

8. High grade PIN: Present.

9. Treatment effect: Not identified.

Surgical Margin Status:

1. See comment below.

Lymph Node Status:

1. Total number of lymph nodes received (utilizing all specimens): 13.

2. Total number of lymph nodes containing metastatic carcinoma: None (0/13).

Other:

1. Other significant findings: Benign prostatic hyperplasia, chronic prostatitis.

2. pTNM stage: pT2c, N0.

COMMENTS:

In the left posterior region in an area of perineuronal invasion, the tumor is well within 0.1 cm of the inked surface and in one area cannot be determined with absolute certainty whether it has reached the inked surface or not.

[page 2 of 3]
The area where this is occurring is relatively limited measuring approximately 0.4 cm in maximum extent. In conclusion, while tumor cannot unequivocally be identified at the inked surface, the presence of perineuronal invasion raises cause for concern that this may have happened.

CLINICAL HISTORY:

Preoperative Diagnosis:

Postoperative Diagnosis:

Symptoms/Radiologic Findings:

SPECIMENS:

A. Right side pelvic lymph node

B. Left side pelvic lymph node

C. Prostate

CODES:

88307

88307

88309

GROSS DESCRIPTION:

The specimen is received in three containers labeled

A. Additionally labeled right side pelvic lymph nodes and contains a 5.3 x 5.0 x 2.4 cm aggregate of yellow tan fibrofatty soft tissue. On palpation, multiple firm fatty possible lymph nodes are identified ranging from 0.7 up to 3.0 cm in greatest dimension. They are entirely submitted in cassettes A1-A8 labeled designated as follows:

A1-- three whole possible lymph nodes; A2-A4-- one whole possible bisected lymph node in each cassette; A5-A6-- one whole possible bisected lymph node; A7-A8-- one whole possible trisected lymph node.

B. Additionally labeled left pelvic lymph node and contains a 5.5 x 3.5 x 1.8 cm aggregate of yellow tan fibrofatty soft tissue. On palpation, three possible firm fatty lymph nodes are identified ranging from 1.4 up to 4.0 cm in greatest dimension. They are entirely submitted in cassettes B1-B4 labeled designated as follows: B1-B2-- two whole possible bisected lymph nodes in each cassette;

B3-B4-- one whole possible quadrisected lymph node.

C. Additionally labeled prostate and contains a 70.9 gram, 5.0 x 4.5 x 4.0 cm prostate received with attached bilateral adnexa having overall dimensions of 4.4 x 2.7 x 1.0 cm. The capsule is pink tan and shaggy. The specimen is inked as follows: Right side blue and left side black. The base and apical margins are coned and serially sectioned. The remainder of the specimen is serially sectioned from apex to base to reveal a 2.0 x 1.5 x 1.0 cm ill defined tan orange mass located in the posterior aspect. This mass extends to within less than 0.1 cm of the inked capsule and involves

[page 3 of 3]
the right and left lobes. The remainder of the cut surface is pink tan and focally cystic diffuse periurethral nodularity. Tan brown calculi are identified. Additional lesions are not present. Representative sections are submitted in cassettes C1-C18 labeled designated as follows: 1-- right prostate/seminal vesicle junction; 2-- left prostate/seminal vesicle junction; 3-4-- apical margin, perpendicular; 5-6-- base margin, perpendicular; 7-9-- right anterior, apex to base; 10-12-- right posterior, apex to base; 13-15-- left anterior, apex to base; 16-18-- left posterior, apex to base.

Additionally, a yellow and green cassette are submitted for genomics research each labeled [REDACTED]

Source: NCI Genomic Data Commons file 2725e002-e6ad-4316-aa62-3e6b01ff4830 (TCGA-HC-7736.D5CB57CB-FF9A-4C83-B019-7B5ED2CD7494.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).